FM case AD1010 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/14f5f46e-d1d4-4384-a8d7-ce55de157d3b

Female, 52.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
